Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DU, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DU-01A (Primary Tumor).

	lw	10/21/11

SPECIMEN TAKEN: 1

FINAL DIAGNOSIS -----
LEFT THYROID (LOBECTOMY):

SPECIMEN TYPE:
Left lobectomy.

TUMOR SITE:
Left lobe.

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

lw
10/21/11

HISTOLOGIC TYPE:
Papillary carcinoma.

TUMOR SIZE:
Greatest dimension 1.4 cm.

FOCALITY:
Unifocal.

LYMPH NODES:
Metastatic carcinoma in 1 of 2 lymph nodes (AE1/AE3 keratin stain). No extracapsular extension.

EXTENT OF INVASION
PRIMARY TUMOR:
pT1: tumor size <2 cm, limited to thyroid.

REGIONAL LYMPH NODES:
pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) node

DISTANT METASTASIS:
pMx: cannot be assessed.

MARGINS:
Involved by invasive carcinoma. (Focal). Specify margin: posterior.

ADDITIONAL PATHOLOGIC FINDINGS:
Thyroiditis, Hashimoto's. Psammoma bodies are identified in a lymph node at the isthmus margin.

This case was shown at the

Source: NCI Genomic Data Commons file 21c670e7-ecf5-4b8d-b9d7-5baf4f4bcb78 (TCGA-ET-A3DU.6AB7842E-8DC5-458A-8AE0-AE429E095DCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).